Gene-level copy-number profile of tumor specimen TCGA-C4-A0F1-01A from TCGA case TCGA-C4-A0F1, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 71.7 years (26,178 days).
Specimen TCGA-C4-A0F1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.f09e8ad8-3775-47c7-9e67-4c7f4b01438e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C4-A0F1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate.
https://portal.gdc.cancer.gov/files/945884a9-b111-4841-8487-79cae36f0c5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 49; copy number 1: 3,105; copy number 2: 44,926; copy number 3: 5,887; copy number 4: 3,440; copy number 5: 2,362; copy number 6: 49.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,992,543–141,208,376, 3 genes: Y_RNA, RNU6-904P, RPS16P3.
- chr2:195,003,711–195,026,370, 1 gene: AC010983.1.
- chr2:212,832,161–212,937,520, 5 genes: PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr3:103,630,661–103,630,912, 1 gene: TUBBP11.
- chr4:14,111,968–14,242,813, 3 genes: LINC01085, AC073848.1, AC092546.1.
- chr5:85,549,409–85,549,952, 1 gene: AC026700.1.
- chr6:22,589,137–22,593,833, 1 gene: AL033539.1.
- chr7:126,495,312–126,531,336, 2 genes (within-gene range 0–2): AC002057.2, AC000374.1.
- chr9:21,802,636–23,438,700, 21 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:80,563,571–80,565,962, 2 genes: MTCO1P51, MTND2P9.
- chr11:21,383,801–21,383,909, 1 gene: RNA5SP337.
- chr11:112,977,353–112,977,420, 1 gene: RNU7-187P.
- chr12:28,505,394–28,505,528, 1 gene: RNA5SP355.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,411 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:192,716,132–248,919,946, 1,214 genes, copy number 5 (broad region; genes not listed).
- chr3:108,549,864–109,977,767, 29 genes, copy number 5: CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1.
- chr3:163,109,152–163,361,563, 1 gene, copy number 5 (within-gene range 0–5): LINC01192.
- chr3:163,455,568–198,222,513, 640 genes, copy number 5 (broad region; genes not listed).
- chr8:37,326,575–42,129,249, 117 genes, copy number 5 (broad region; genes not listed).
- chr8:107,186,997–122,127,184, 126 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:131,904,093–145,066,685, 284 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
